Somatic mutation profile of tumor specimen TCGA-MX-A666-01A (aliquot TCGA-MX-A666-01A-11D-A31L-08) from TCGA case TCGA-MX-A666, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,288 days).
Specimen TCGA-MX-A666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bf7047a-4a1c-4115-9ded-72d6ef236735.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MX-A666-10A (Blood Derived Normal), aliquot TCGA-MX-A666-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3e66e75-7d75-4bdb-a7f9-848ca8a224cd

The open-access MAF lists 112 somatic variants for this specimen: 85 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 25, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 3, Nonsense Mutation 2, RNA 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 19/59 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039483, CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRG1 | c.1952-1G>A p.X651_splice | Splice Site (SNP) | VAF 26/82 reads (32%) | catalogued as rs1207621709, COSV100342126; called by muse, mutect2, varscan2
- AGA | c.936T>G p.S312R | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV99219390; called by muse, mutect2, varscan2
- APC | c.7735G>T p.E2579* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as COSV99965861; called by muse, mutect2, varscan2
- ASAH2 | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 79/554 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV100269822; called by muse, mutect2, varscan2
- ASPH | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101063495; called by muse, mutect2, varscan2
- ATF7IP2 | c.153G>C p.Q51H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100202530, COSV61092196; called by muse, mutect2, varscan2
- ATF7IP2 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100202532; called by muse, mutect2, varscan2
- B3GALNT2 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs541697587, COSV100782760; ClinVar: uncertain significance; called by muse, mutect2
- BAG6 | c.2719C>G p.L907V (on ENST00000676571; = p.L860V on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99276517; called by muse, mutect2
- BCORL1 | c.2432del p.A811Efs*42 | Frame Shift Del (DEL) | VAF 47/106 reads (44%) | catalogued as COSV99499438; called by mutect2, pindel, varscan2
- BRD2 | c.2100G>T p.E700D | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV100875581; called by muse, mutect2, varscan2
- CARM1 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99449867; called by muse, mutect2, varscan2
- CCDC116 | c.1034A>G p.D345G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99489161; called by muse, mutect2, varscan2
- CD1C | c.873C>A p.D291E | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100939357, COSV63807806; called by muse, mutect2, varscan2
- CDC25B | c.678G>C p.Q226H (on ENST00000245960 / NM_021873.3; = p.Q212H on NM_004358.4) | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV99847676; called by muse, mutect2
- CPLX1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100408229; called by muse, mutect2
- CTSW | c.981G>C p.W327C | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100327222; called by muse, mutect2
- CUX2 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as COSV55640580; called by muse, mutect2, varscan2
- DAGLA | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV99944053; called by muse, mutect2, varscan2
- DIRAS2 | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101005818; called by muse, mutect2, varscan2
- DPM1 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100857689, COSV100857760; called by muse, mutect2, varscan2
- DUOX1 | c.2533G>T p.V845L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV100367684; called by muse, mutect2, varscan2
- EHBP1L1 | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs773127792, COSV58571632; called by muse, mutect2, varscan2
- EMILIN2 | c.1964C>T p.T655I | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99598203; called by muse, mutect2
- FCRL3 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.085); catalogued as rs753184362, COSV63842572; called by muse, mutect2, varscan2
- FCRL5 | c.1517A>G p.Q506R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV100708598; called by muse, mutect2, varscan2
- FLG2 | c.5265A>C p.Q1755H | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.839); catalogued as COSV101165634; called by muse, mutect2
- GEM | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52598848, COSV99891132; called by muse, mutect2, varscan2
- GNG13 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200381353, COSV50210270; called by muse, mutect2, varscan2
- GPATCH8 | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as rs762758258, COSV100132496; called by muse, mutect2, varscan2
- GRIP1 | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV99668348; called by muse, mutect2, varscan2
- HRH4 | c.608A>C p.K203T | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99907741; called by muse, mutect2, varscan2
- HYDIN | c.1150A>C p.T384P | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99862205; called by mutect2, varscan2
- IFIH1 | c.2330A>G p.K777R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as rs1286741340, COSV99718451; called by mutect2, varscan2
- IL4R | c.2207C>T p.T736I | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99404799; called by muse, mutect2
- INTS8 | c.2741A>C p.K914T | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100353649; called by muse, mutect2
- KEAP1 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.233); catalogued as COSV99407419; called by muse, mutect2
- LAMA5 | c.8180G>A p.R2727Q | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778000345, COSV53357230, COSV99438425; called by muse, mutect2
- LRIG3 | c.1796T>G p.V599G | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100292457; called by muse, mutect2
- LRRC1 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100906236; called by muse, mutect2, varscan2
- LRRN1 | c.1866C>A p.D622E | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100076091; called by muse, mutect2, varscan2
- LRRN3 | c.776T>A p.V259D | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100068426; called by muse, mutect2
- MBOAT7 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as rs368420662; called by muse, mutect2, varscan2
- MUC4 | c.200A>T p.N67I | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.712); catalogued as COSV100639872; called by muse, mutect2
- NEXMIF | c.4337A>G p.K1446R | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771736722, COSV50021524, COSV99281693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSD1 | c.2707C>A p.P903T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100728539; called by muse, mutect2, varscan2
- NXPE3 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs760288885, COSV56292891; called by muse, mutect2, varscan2
- OPN1SW | c.445C>G p.H149D | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99975514; called by muse, mutect2, varscan2
- PCDHA12 | c.2022G>T p.Q674H | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV99165149; called by muse, mutect2, varscan2
- PCDHA5 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.801); catalogued as rs147205231, COSV65352077; called by muse, mutect2
- PDE6B | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99727012; called by muse, mutect2, varscan2
- PDZD8 | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100559420; called by muse, mutect2, varscan2
- PLA2G6 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs763352728, COSV59270744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTDSS1 | c.179+1G>A p.X60_splice | Splice Site (SNP) | VAF 37/141 reads (26%) | catalogued as COSV99749613; called by muse, mutect2, varscan2
- PTPRM | c.3736G>T p.A1246S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100155452; called by muse, mutect2, varscan2
- RGS22 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100693031, COSV62664027; called by muse, mutect2, varscan2
- SHQ1 | c.1023G>A p.M341I | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV100344680; called by muse, mutect2
- SLC8A3 | c.2645G>A p.R882Q (on ENST00000381269 / NM_183002.3; = p.R880Q on NM_033262.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99385346; called by muse, mutect2
- SON | c.3419A>C p.Y1140S | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99277127; called by muse, mutect2, varscan2
- SYCP2L | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99304771; called by muse, mutect2, varscan2
- TIAM2 | c.1843G>A p.V615I | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100018162; called by muse, mutect2, varscan2
- TP63 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.353); catalogued as COSV53202068; called by muse, mutect2, varscan2
- TPPP | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1335924594, COSV100862758; called by muse, mutect2, varscan2
- TPRN | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100285716; called by muse, mutect2
- TXNDC2 | c.275C>G p.S92C (on ENST00000306084 / NM_001098529.2; = p.S25C on NM_032243.6) | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.971); catalogued as COSV100045814; called by muse, mutect2
- UBQLN4 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs1203600369, COSV100849072; called by muse, mutect2, varscan2
- UGT2B28 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553814134, COSV100158600; called by muse, mutect2
- USP17L2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.3); catalogued as COSV100414530; called by muse, mutect2, varscan2
- USP24 | c.5462G>A p.R1821H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs1333432275, COSV53771035; called by muse, mutect2, varscan2
- USP34 | c.2484T>A p.H828Q | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV101276748; called by muse, mutect2, varscan2
- WDR20 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54472578; called by muse, mutect2
- WRAP53 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs746794861, COSV99377729; called by muse, mutect2, varscan2
- ZFAND2A | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 16/496 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100335832; called by muse, mutect2
- ZW10 | c.1735C>A p.P579T | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99562487; called by muse, mutect2, varscan2
- AATF | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- CDC5L | c.805dup p.R269Kfs*6 | Frame Shift Ins (INS) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- CNTFR | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CNTNAP1 | c.2432_2434del p.F811del | In Frame Del (DEL) | VAF 93/598 reads (16%) | called by mutect2, pindel, varscan2
- DPF3 | c.614del p.K205Sfs*67 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- HNRNPDL | c.604_605dup p.D203Lfs*7 | Frame Shift Ins (INS) | VAF 17/176 reads (10%) | called by mutect2, pindel
- MUC16 | c.27306del p.F9102Lfs*18 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | called by mutect2, pindel, varscan2
- PDS5A | c.1634dup p.N545Kfs*4 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- PTPN12 | c.2266_2267del p.E756Sfs*8 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | called by mutect2, pindel, varscan2
- SNAP25 | c.114+2dup p.X38_splice | Splice Site (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel
- AKNA | c.567C>T p.V189= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV56312058; called by muse, mutect2
- BTBD2 | c.543C>T p.D181= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99724577; called by muse, mutect2
- DLG3 | c.1953A>G p.K651= (on ENST00000374360 / NM_021120.4; = p.K346= on NM_020730.3) | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV99529245; called by muse, mutect2, varscan2
- FSCN3 | c.507C>T p.D169= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as rs371544770; called by muse, mutect2, varscan2
- GTPBP1 | c.1275C>T p.D425= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99322974; called by muse, mutect2, varscan2
- KCNG1 | c.1194C>T p.I398= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV65369599; called by muse, mutect2, varscan2
- KLF15 | c.696G>A p.S232= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1163157939, COSV99955085; called by muse, mutect2, varscan2
- MEF2D | c.1341T>C p.R447= | Silent (SNP) | VAF 16/227 reads (7%) | catalogued as COSV100559869; called by muse, mutect2
- MRC2 | c.2457C>T p.P819= | Silent (SNP) | VAF 13/243 reads (5%) | catalogued as COSV57639433; called by muse, mutect2
- MSL2 | c.1458C>T p.N486= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV99386570; called by muse, mutect2
- MYH10 | c.2301G>A p.K767= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV52597762; called by muse, mutect2, varscan2
- NDST1 | c.57C>T p.V19= | Silent (SNP) | VAF 12/187 reads (6%) | called by muse, mutect2
- NINL | c.2964G>A p.R988= | Silent (SNP) | VAF 8/172 reads (5%) | catalogued as COSV99624802; called by muse, mutect2
- NOP53 | c.102G>A p.L34= | Silent (SNP) | VAF 17/195 reads (9%) | catalogued as COSV54410079, COSV99621699; called by muse, mutect2
- OR5AU1 | c.693C>T p.A231= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100436085; called by muse, mutect2, varscan2
- OR6B2 | c.822C>T p.I274= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV99401239; called by muse, mutect2
- OTUD7B | c.1512C>T p.N504= | Silent (SNP) | VAF 90/391 reads (23%) | catalogued as COSV100967388; called by muse, mutect2, varscan2
- PTPRZ1 | c.687C>T p.Y229= | Silent (SNP) | VAF 19/180 reads (11%) | catalogued as COSV101099698; called by muse, mutect2, varscan2
- RIC1 | c.1971C>T p.I657= | Silent (SNP) | VAF 56/124 reads (45%) | catalogued as COSV52613318, COSV99316819; called by muse, mutect2, varscan2
- RTL3 | c.459C>A p.P153= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV58183568, COSV58184339; called by muse, mutect2, varscan2
- SYNE2 | c.9660T>G p.S3220= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV100646932; called by muse, mutect2, varscan2
- TGS1 | c.2088C>T p.D696= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as rs762100787, COSV52703068; called by muse, mutect2
- TTN | c.2061A>G p.Q687= (on ENST00000591111; = p.Q641= on NM_003319.4) | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as rs188680791, COSV59871041; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZCCHC7 | c.228C>A p.V76= | Silent (SNP) | VAF 24/286 reads (8%) | catalogued as COSV100382831; called by muse, mutect2
- ZNF697 | c.1152C>T p.G384= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1269049110, COSV101360068; called by muse, mutect2, varscan2
- AC005863.1 | n.321T>C | RNA (SNP) | VAF 18/120 reads (15%) | catalogued as rs371591244; called by muse, mutect2, varscan2
- AL109984.1 | n.186+4851C>T | Intron (SNP) | VAF 67/310 reads (22%) | catalogued as rs373948550; called by muse, mutect2, varscan2
